Gene-level copy-number profile of tumor specimen TCGA-YA-A8S7-01A from TCGA case TCGA-YA-A8S7, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 69.0 years (25,188 days).
Specimen TCGA-YA-A8S7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.b61e6ffc-b5fe-4ca0-a943-09d2811e5062.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-YA-A8S7-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/733f4e2e-2aa6-442e-a1bd-74c48a97a68d

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 386; copy number 2: 6,508; copy number 3: 17,394; copy number 4: 24,708; copy number 5: 1,418; copy number 6: 7,084; copy number 7: 112; copy number 8: 1,534; copy number 9: 673.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-YA-A8S7-01A-11D-A36W-01): tumor purity 0.36, ploidy 3.68, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 673 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–158,203,877, 673 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 386. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
